Somatic mutation profile of tumor specimen TCGA-D3-A2JG-06A (aliquot TCGA-D3-A2JG-06A-11D-A196-08) from TCGA case TCGA-D3-A2JG, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 39.2 years (14,330 days).
Specimen TCGA-D3-A2JG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be3eddd2-bbac-4bfc-b8f6-7a5cc0333109.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2JG-10A (Blood Derived Normal), aliquot TCGA-D3-A2JG-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87085ef9-565f-4494-b718-a7d7d0a24119

The open-access MAF lists 131 somatic variants for this specimen: 78 protein-altering or splice-affecting, 49 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 49, Nonsense Mutation 4, Frame Shift Del 2, RNA 2, 5'Flank 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADCY8 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs992601985, COSV53914249; called by muse, mutect2, varscan2
- AIFM3 | c.1223A>T p.K408M | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53148768; called by mutect2, varscan2
- ALPK2 | c.3155C>T p.P1052L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.225); catalogued as rs769727633, COSV64492923; called by muse, mutect2, varscan2
- ATRN | c.3484G>A p.D1162N | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV53529881, COSV99497657; called by muse, mutect2, varscan2
- BACH2 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as COSV57585662, COSV57598514; called by muse, mutect2, varscan2
- CD163 | c.2378C>T p.S793F | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1201443489, COSV63130616, COSV63130688; called by muse, mutect2, varscan2
- CDH20 | c.1637G>A p.R546K | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.122); catalogued as COSV99404034; called by muse, mutect2, varscan2
- CFAP206 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1405987812, COSV65806689; called by muse, mutect2, varscan2
- CLCA1 | c.1543G>T p.D515Y | Missense Mutation (SNP) | VAF 57/66 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52328887; called by muse, mutect2, varscan2
- CLRN1 | c.307C>T p.L103F (on ENST00000327047 / NM_174878.3; = p.L27F on NM_052995.2) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV55806145; called by muse, mutect2, varscan2
- COL19A1 | c.2795G>A p.G932E | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59577713; called by muse, mutect2, varscan2
- COL5A3 | c.4198G>A p.G1400R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV53413642; called by muse, mutect2, varscan2
- DCC | c.4009C>T p.R1337* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as rs773315729, COSV71427767; called by muse, mutect2, varscan2
- DENND5B | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100170729; called by muse, mutect2, varscan2
- DIS3L2 | c.1892C>T p.P631L | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as COSV99805087; called by muse, varscan2
- DNAH5 | c.12706G>A p.G4236S | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.919); catalogued as COSV54236085; called by muse, varscan2
- DNM2 | c.2483C>T p.P828L (on ENST00000355667 / NM_001005360.3; = p.P824L on NM_004945.3) | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs778083613, COSV53034026; called by muse, varscan2
- EHBP1L1 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs556715013, COSV58573831; called by muse, mutect2, varscan2
- EPB41L4B | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 51/62 reads (82%) | SIFT tolerated (0.13); PolyPhen benign (0.145); catalogued as COSV65803872; called by muse, mutect2, varscan2
- FBN2 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs866719857, COSV52499675, COSV52517342, COSV99331150; called by muse, mutect2, varscan2
- FER1L5 | c.4220A>C p.E1407A (on ENST00000623019; = p.E1380A on NM_001293083.2) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV101208787; called by muse, mutect2, varscan2
- FGF23 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99426174; called by muse, mutect2, varscan2
- FLCN | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 84/145 reads (58%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV53260877; called by muse, mutect2, varscan2
- GRIA4 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1425201356, COSV56905223, COSV99233559; called by muse, mutect2, varscan2
- HRG | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV51643806; called by muse, mutect2, varscan2
- INHBC | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV59005591; called by muse, mutect2, varscan2
- IPCEF1 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54546370; called by muse, mutect2, varscan2
- IRAK1 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs200423500, COSV57655131; called by muse, mutect2, varscan2
- IRGC | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as COSV54984980; called by muse, mutect2, varscan2
- ITPRID1 | c.1965C>G p.D655E | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as COSV60077397; called by muse, mutect2, varscan2
- KDM5A | c.4775C>T p.P1592L | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101238549; called by muse, mutect2, varscan2
- LAMA2 | c.2710G>A p.G904R | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70350974; called by muse, mutect2, varscan2
- MLF2 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs779857326, COSV99180048; called by mutect2, varscan2
- MLF2 | c.402C>T p.I134= | Splice Region (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99180049; called by muse, mutect2, varscan2
- NACC1 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52835066; called by muse, mutect2, varscan2
- NEXMIF | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1247214773, COSV50046716; called by muse, mutect2, varscan2
- NFIX | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); catalogued as rs1256133151, COSV62176628; called by mutect2, varscan2
- NLGN4Y | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 53/69 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV59297392; called by muse, mutect2, varscan2
- NXF3 | c.230A>G p.K77R | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67704251; called by muse, mutect2, varscan2
- OR2A12 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 104/348 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373620683; called by muse, varscan2
- PALM2AKAP2 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.006); catalogued as COSV57124819; called by muse, mutect2, varscan2
- PCNX2 | c.5222C>T p.S1741F | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs866568964, COSV50821248; called by muse, mutect2, varscan2
- PDE4A | c.1832C>T p.A611V (on ENST00000380702 / NM_001111307.2; = p.A372V on NM_006202.3) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV99533440; called by muse, mutect2, varscan2
- PLAAT1 | c.542G>A p.G181E (on ENST00000650797; = p.G76E on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53232051; called by muse, mutect2, varscan2
- PRKAG3 | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV52102608; called by muse, mutect2, varscan2
- PRXL2C | c.476G>A p.W159* | Nonsense Mutation (SNP) | VAF 46/115 reads (40%) | catalogued as COSV64450326; called by muse, mutect2, varscan2
- RABGAP1L | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 132/177 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV52306407; called by muse, mutect2, varscan2
- RGR | c.870G>T p.E290D | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs997944407, COSV63894571; called by muse, mutect2, varscan2
- SEL1L3 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53544197; called by muse, mutect2, varscan2
- SEMA3E | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as rs965528935, COSV57082291; called by muse, mutect2, varscan2
- SLC18A1 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as COSV52349166; called by muse, mutect2, varscan2
- SLC22A9 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs981863759, COSV54165630, COSV99655407; called by muse, mutect2, varscan2
- SLC8A3 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63518602; called by muse, mutect2
- SMYD3 | c.1100C>T p.P367L (on ENST00000490107 / NM_001375962.1; = p.P308L on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100830600; called by muse, mutect2, varscan2
- SPEF2 | c.4639C>T p.P1547S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57430247; called by muse, mutect2, varscan2
- STAB1 | c.4726G>A p.G1576R | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58739292; called by muse, mutect2, varscan2
- STAT4 | c.2230C>T p.P744S | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.968); catalogued as COSV61830831; called by muse, mutect2, varscan2
- STIL | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV54551483; called by muse, mutect2, varscan2
- TAS2R39 | c.762G>A p.M254I | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV71470888; called by muse, mutect2, varscan2
- TBC1D32 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV51548935, COSV99249239; called by muse, mutect2, varscan2
- TDRD3 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as rs1377593794, COSV52158917; called by muse, mutect2, varscan2
- TEKT3 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0.315); catalogued as COSV58628345; called by muse, mutect2, varscan2
- TENM4 | c.6598G>A p.G2200S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs770034158, COSV53642714; called by muse, mutect2, varscan2
- THBS2 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV64680065; called by muse, mutect2, varscan2
- TMEM164 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV55813527; called by muse, mutect2, varscan2
- TNPO3 | c.2120T>G p.L707R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55283431; called by muse, mutect2, varscan2
- TTN | c.9376A>G p.K3126E (on ENST00000591111; = p.K3080E on NM_003319.4) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | PolyPhen benign (0); catalogued as COSV60164612; called by muse, mutect2, varscan2
- UMOD | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as COSV56777023; called by muse, mutect2, varscan2
- USP44 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV51565143; called by muse, mutect2, varscan2
- WDR90 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1482866901, COSV53472013; called by muse, varscan2
- WWC2 | c.3373G>A p.A1125T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV67859682; called by muse, mutect2, varscan2
- ZNF280C | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV63969299; called by muse, varscan2
- ZNF557 | c.919C>T p.H307Y (on ENST00000414706 / NM_001044388.2; = p.H314Y on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53274472; called by muse, mutect2, varscan2
- ZNF668 | c.1177del p.H393Tfs*15 | Frame Shift Del (DEL) | VAF 53/192 reads (28%) | catalogued as COSV56213142; called by mutect2, pindel, varscan2
- ZNF681 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68073554; called by muse, mutect2, varscan2
- ZSCAN30 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV54351233; called by muse, mutect2, varscan2
- VPS8 | c.1128_1131del p.V377Ifs*5 (on ENST00000625842 / NM_001349294.1; = p.V375Ifs*5 on NM_015303.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 53/109 reads (49%) | called by mutect2, pindel, varscan2
- ADSS1 | c.246C>T p.F82= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV58274580; called by muse, mutect2, varscan2
- C2CD3 | c.5820G>T p.G1940= | Silent (SNP) | VAF 71/183 reads (39%) | catalogued as COSV58094971; called by muse, mutect2, varscan2
- CARTPT | c.285G>A p.R95= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV57115487; called by muse, mutect2, varscan2
- CDH20 | c.1638G>A p.R546= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as rs998003970, COSV99404036; called by muse, mutect2, varscan2
- CFC1 | c.189G>A p.G63= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV52090635; called by muse, varscan2
- CR2 | c.1281C>T p.V427= | Silent (SNP) | VAF 54/70 reads (77%) | catalogued as COSV65508422; called by muse, mutect2, varscan2
- DENND5B | c.2319G>A p.E773= | Silent (SNP) | VAF 62/156 reads (40%) | catalogued as rs1198677858, COSV100170730; called by muse, mutect2, varscan2
- DNM2 | c.2500C>A p.R834= (on ENST00000355667 / NM_001005360.3; = p.R830= on NM_004945.3) | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as rs367898095, COSV53035003; called by muse, varscan2
- FAM193B | c.1503C>T p.G501= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV61558134; called by muse, mutect2, varscan2
- FAM47B | c.1659C>T p.F553= | Silent (SNP) | VAF 56/94 reads (60%) | catalogued as rs1445597831, COSV61453228; called by muse, mutect2, varscan2
- FGD2 | c.1638G>A p.L546= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as COSV51462967; called by muse, mutect2, varscan2
- FGF23 | c.120C>T p.I40= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV52978147, COSV99426176; called by muse, mutect2, varscan2
- GRIK3 | c.2745C>T p.A915= | Silent (SNP) | VAF 44/58 reads (76%) | catalogued as COSV66136003; called by muse, mutect2, varscan2
- HJURP | c.1455G>A p.L485= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV64978778, COSV64979020; called by muse, mutect2, varscan2
- KCNJ6 | c.10C>T p.L4= | Silent (SNP) | VAF 223/600 reads (37%) | catalogued as rs757384670, COSV55717449; called by muse, mutect2, varscan2
- KDM5A | c.4776C>T p.P1592= | Silent (SNP) | VAF 38/133 reads (29%) | catalogued as COSV101238548; called by muse, mutect2, varscan2
- KIF21A | c.708A>G p.Q236= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV62773937; called by muse, mutect2, varscan2
- LMAN2 | c.993C>T p.L331= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs781677039, COSV57425029; called by muse, mutect2, varscan2
- MUC1 | c.3354C>A p.T1118= (on ENST00000611571 / NM_001371720.1; = p.T129= on NM_002456.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/35 reads (86%) | catalogued as COSV58116030; called by muse, mutect2, varscan2
- MYOF | c.1062C>T p.A354= | Silent (SNP) | VAF 30/44 reads (68%) | catalogued as rs1178421182, COSV100825082; called by muse, mutect2, varscan2
- NAV3 | c.75G>A p.P25= | Silent (SNP) | VAF 55/164 reads (34%) | catalogued as rs369240432, COSV57091573; called by muse, mutect2, varscan2
- NFIX | c.792G>A p.R264= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV100666245; called by muse, mutect2, varscan2
- NHLH1 | c.318C>T p.P106= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV57483927; called by muse, mutect2, varscan2
- NPAS3 | c.2079C>T p.S693= (on ENST00000356141 / NM_001164749.2; = p.S661= on NM_022123.3) | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV60843301; called by muse, mutect2, varscan2
- OPRPN | c.438C>T p.I146= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV68193166; called by muse, mutect2, varscan2
- OR2T3 | c.801G>A p.P267= | Silent (SNP) | VAF 124/307 reads (40%) | catalogued as rs370677701; called by muse, mutect2, varscan2
- OR51V1 | c.33G>A p.T11= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs550954546, COSV58314225; called by muse, mutect2, varscan2
- P4HA3 | c.303G>A p.R101= | Silent (SNP) | VAF 128/310 reads (41%) | catalogued as COSV59041937; called by muse, mutect2, varscan2
- PCDH10 | c.1470G>A p.R490= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV52097812; called by muse, mutect2, varscan2
- PDE4A | c.1833C>T p.A611= (on ENST00000380702 / NM_001111307.2; = p.A372= on NM_006202.3) | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs746027578, COSV99533448; called by mutect2, varscan2
- PHF2 | c.1092C>T p.P364= | Silent (SNP) | VAF 209/258 reads (81%) | catalogued as COSV63681918; called by muse, mutect2, varscan2
- RFX6 | c.198G>A p.P66= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1305170504, COSV60586659; called by muse, mutect2, varscan2
- SCN2A | c.4011C>T p.I1337= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV51846718; called by muse, mutect2, varscan2
- SCN5A | c.1725G>A p.Q575= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as COSV61129865; called by muse, mutect2, varscan2
- SEC14L4 | c.1173G>A p.E391= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs146895070; called by muse, mutect2, varscan2
- SERPINB13 | c.702G>A p.G234= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV54029660; called by muse, mutect2, varscan2
- SLC22A10 | c.1431G>A p.R477= | Silent (SNP) | VAF 51/135 reads (38%) | catalogued as COSV60422051; called by muse, mutect2, varscan2
- SLC22A7 | c.1179C>T p.V393= (on ENST00000372585 / NM_153320.2; = p.V391= on NM_006672.3) | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV51484649; called by muse, mutect2, varscan2
- SPAG8 | c.663G>A p.V221= | Silent (SNP) | VAF 99/137 reads (72%) | catalogued as COSV52414588; called by muse, mutect2, varscan2
- SPAM1 | c.591G>A p.K197= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as COSV56145234; called by muse, mutect2, varscan2
- SPHKAP | c.2979G>A p.R993= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV60867997; called by muse, varscan2
- SPTB | c.2088C>T p.I696= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV67631985; called by muse, varscan2
- SSTR1 | c.217C>T p.L73= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV57456658; called by muse, varscan2
- TENM4 | c.7428C>T p.L2476= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV53642698; called by muse, mutect2, varscan2
- TIAM2 | c.1938G>A p.K646= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs1369248185, COSV59688805, COSV59697200; called by muse, mutect2, varscan2
- TMEM259 | c.534G>T p.V178= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV52261425; called by muse, mutect2, varscan2
- TP63 | c.336G>A p.T112= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as rs267599728, COSV53196338; called by muse, mutect2, varscan2
- TRBV5-1 | c.90G>A p.L30= | Silent (SNP) | VAF 31/52 reads (60%) | called by muse, mutect2, varscan2
- ZNF385B | c.618G>A p.T206= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs776781514, COSV61175207; called by muse, mutect2, varscan2
- MGAM | c.4618+8690G>A | Intron (SNP) | VAF 13/42 reads (31%) | catalogued as COSV101527345; called by muse, mutect2, varscan2
- OSTCP1 | n.451C>T | RNA (SNP) | VAF 36/110 reads (33%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:74894197 ins T | 5'Flank (INS) | VAF 28/117 reads (24%) | called by mutect2, pindel, varscan2
- ZNF322P1 | n.379T>C | RNA (SNP) | VAF 145/203 reads (71%) | called by muse, mutect2, varscan2
